Somatic mutation profile of tumor specimen MP2PRT-PAVZKG-TMP1-A (aliquot MP2PRT-PAVZKG-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVZKG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (773 days).
Specimen MP2PRT-PAVZKG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 71a09b64-3b0f-4143-bc01-108ecf38948d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVZKG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVZKG-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7889786c-d0a2-4eb5-95c2-629b0d983cc9

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 8, Silent 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO9 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 61/356 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs377188275; called by muse, mutect2, varscan2
- CTDSP1 | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 25/499 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV56090661; called by muse, mutect2
- KYNU | c.314G>C p.G105A | Missense Mutation (SNP) | VAF 23/429 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs756839567, COSV51581617; called by muse, mutect2
- MSX2 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 64/439 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs756030049; called by muse, mutect2, varscan2
- ANO8 | c.2682G>C p.Q894H | Missense Mutation (SNP) | VAF 18/524 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2
- AP1M1 | c.367C>A p.P123T | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGKV2-24 | chr2:89176326 TGA>ACCCC | Missense Mutation (INS) | VAF 28/149 reads (19%) | called by pindel, varscan2*
- RTN4 | c.1175_1176insCCCCGG p.R392_V393insPG | In Frame Ins (INS) | VAF 44/371 reads (12%) | called by mutect2, pindel, varscan2
- TELO2 | c.754T>A p.C252S | Missense Mutation (SNP) | VAF 80/564 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- COL11A1 | c.1173T>C p.D391= | Silent (SNP) | VAF 17/394 reads (4%) | called by muse, mutect2
- GLDN | c.786G>T p.R262= | Silent (SNP) | VAF 86/453 reads (19%) | called by muse, mutect2, varscan2
- MTHFSD | c.1125G>A p.A375= (on ENST00000360900 / NM_001159377.2; = p.A374= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/331 reads (16%) | catalogued as rs537395734; called by muse, mutect2, varscan2
